Somatic mutation profile of tumor specimen TCGA-EF-5830-01A (aliquot TCGA-EF-5830-01A-01D-1657-10) from TCGA case TCGA-EF-5830, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.2 years (19,802 days).
Specimen TCGA-EF-5830-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9364f79-3002-4ed8-b64d-35bcf8952abb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EF-5830-10A (Blood Derived Normal), aliquot TCGA-EF-5830-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6161b991-ec15-4f7f-8f84-46df6af44280

The open-access MAF lists 62 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 41, Silent 16, Nonsense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 99/194 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC52A2 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514658, CM130746, COSV57351385, COSV57352514; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 35/47 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1330A>C p.M444L | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51419452, COSV99272737; called by muse, mutect2, varscan2
- ANKS1A | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs541932194, COSV64462458; called by muse, mutect2, varscan2
- APC | c.3859del p.I1287* | Frame Shift Del (DEL) | VAF 136/218 reads (62%) | catalogued as COSV57338028; called by mutect2, pindel, varscan2
- BICD1 | c.1969C>T p.R657W | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs750220029, COSV55683677; called by muse, mutect2, varscan2
- CHRNA4 | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs142137599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 98/164 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs376303610; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 101/146 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs749182596, COSV62624548; called by muse, mutect2, varscan2
- CWF19L1 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); catalogued as rs375717897; called by muse, mutect2, varscan2
- FOXP4 | c.1027C>T p.R343W (on ENST00000307972 / NM_001012426.1; = p.R342W on NM_138457.3) | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV57221773; called by muse, mutect2, varscan2
- HDC | c.627A>T p.K209N | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV51074908; called by muse, mutect2, varscan2
- KNL1 | c.5530C>T p.P1844S (on ENST00000346991 / NM_170589.5; = p.P1818S on NM_144508.5) | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV61157662; called by muse, mutect2, varscan2
- LAMB4 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1477486270, COSV52724840; called by muse, mutect2, varscan2
- MAPKAPK2 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99685889; called by muse, mutect2, varscan2
- MED12L | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV56387477; called by muse, mutect2, varscan2
- MRPS22 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as rs1057269467, COSV60350296; called by muse, mutect2, varscan2
- MUC16 | c.20617G>A p.D6873N | Missense Mutation (SNP) | VAF 166/437 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.25); catalogued as COSV101199803; called by muse, mutect2, varscan2
- NFIX | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1568318723, COSV62178874; called by muse, mutect2, varscan2
- NPR1 | c.1544T>G p.V515G | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV100902017; called by muse, mutect2, varscan2
- PDZD3 | c.1153G>A p.V385M (on ENST00000531114; = p.V305M on NM_024791.4) | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs774352787, COSV52705244; called by muse, mutect2, varscan2
- PHKA2 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV66055199; called by muse, mutect2, varscan2
- POM121L12 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs766537069, COSV68692604; called by muse, mutect2, varscan2
- PRAMEF12 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 126/235 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs369283541; called by muse, mutect2, varscan2
- PSMC1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54321458; called by muse, mutect2, varscan2
- PTPRT | c.3619C>T p.R1207* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as COSV61997319; called by muse, mutect2, varscan2
- RALGDS | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.214); catalogued as COSV64428603; called by muse, mutect2
- RBM8A | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 55/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57162972; called by muse, mutect2, varscan2
- RHOC | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs779520374, COSV99588247; called by muse, mutect2, varscan2
- RPS3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV53705142; called by muse, mutect2, varscan2
- SCN3B | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 28/64 reads (44%) | catalogued as rs1555116005, COSV54800297; called by muse, mutect2, varscan2
- SHPRH | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.074); catalogued as COSV51613845; called by muse, mutect2, varscan2
- SPEG | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs376367804, COSV56667584; called by muse, mutect2, varscan2
- SYNE1 | c.5611G>T p.A1871S (on ENST00000367255 / NM_182961.4; = p.A1878S on NM_033071.3) | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99562911; called by muse, mutect2, varscan2
- SYNM | c.4376C>T p.S1459L | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs782418930, COSV50442005; called by muse, mutect2, varscan2
- TGM5 | c.1561C>G p.Q521E (on ENST00000220420 / NM_201631.4; = p.Q439E on NM_004245.4) | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV55011062; called by muse, mutect2
- TTN | c.47461C>G p.L15821V (on ENST00000591111; = p.L8397V on NM_003319.4) | Missense Mutation (SNP) | VAF 28/203 reads (14%) | PolyPhen benign (0.001); catalogued as COSV60194346; called by muse, mutect2, varscan2
- TUBG2 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV52218773; called by muse, mutect2, varscan2
- UBXN7 | c.1280T>A p.I427N | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV56356696; called by muse, mutect2, varscan2
- UGT3A1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as COSV57100468; called by muse, mutect2, varscan2
- VRTN | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 76/183 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs751966382, COSV56442441; called by muse, mutect2, varscan2
- YIPF5 | c.246T>A p.Y82* | Nonsense Mutation (SNP) | VAF 105/263 reads (40%) | catalogued as COSV50823402; called by muse, mutect2, varscan2
- ZNF568 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 163/364 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1337345861, COSV61742221; called by mutect2, varscan2
- ZP2 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs766836952, COSV54817102; called by muse, mutect2, varscan2
- ATRNL1 | c.2589T>C p.C863= | Silent (SNP) | VAF 62/169 reads (37%) | catalogued as COSV58100579; called by muse, mutect2, varscan2
- B3GALT2 | c.666T>C p.D222= | Silent (SNP) | VAF 47/115 reads (41%) | catalogued as rs376102979, COSV66464340; called by muse, mutect2, varscan2
- CAP1 | c.1335C>A p.G445= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as COSV61223929; called by muse, mutect2, varscan2
- COL5A1 | c.1377G>A p.A459= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs746091599, COSV65672107; called by muse, mutect2, varscan2
- COQ10B | c.45G>A p.S15= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV55837024; called by muse, mutect2, varscan2
- EPHB4 | c.915C>T p.R305= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs139571805; called by muse, mutect2, varscan2
- FIBCD1 | c.903G>A p.A301= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs750732451, COSV53393359; called by muse, mutect2, varscan2
- FRMD4B | c.1404G>C p.L468= | Silent (SNP) | VAF 61/149 reads (41%) | catalogued as COSV68331689; called by muse, mutect2, varscan2
- GPBAR1 | c.792C>T p.S264= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV50308467; called by muse, mutect2, varscan2
- NBL1 | c.408G>T p.V136= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV57030563; called by muse, mutect2, varscan2
- RXFP1 | c.1521A>G p.T507= | Silent (SNP) | VAF 126/344 reads (37%) | catalogued as rs1348674333, COSV57053310; called by muse, mutect2
- RXFP3 | c.774C>T p.R258= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV57506871; called by muse, mutect2, varscan2
- SCN2A | c.1578G>A p.S526= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs141269163; ClinVar: likely benign; called by muse, mutect2, varscan2
- SENP1 | c.1071G>A p.L357= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV99136912; called by muse, mutect2
- SYNE1 | c.11010C>T p.H3670= (on ENST00000367255 / NM_182961.4; = p.H3655= on NM_033071.3) | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as rs143673038, COSV55037884; called by muse, varscan2
- TMTC4 | c.261C>T p.L87= (on ENST00000376234 / NM_001350577.2; = p.L106= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs1412552241, COSV60892962; called by muse, mutect2, varscan2
